Somatic mutation profile of tumor specimen TARGET-10-PARLPB-09A (aliquot TARGET-10-PARLPB-09A-01D) from TARGET case TARGET-10-PARLPB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.4 years (5,252 days).
Specimen TARGET-10-PARLPB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 235ee1ff-ca7f-4801-95be-1fec4db24b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLPB-10A (Blood Derived Normal), aliquot TARGET-10-PARLPB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81782e03-de2c-4766-8638-1752cf4b43b7

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'UTR 2, Silent 2, 3'UTR 1, Nonsense Mutation 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRLF2 | c.695T>G p.F232C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1057519743, COSV67493408; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AXDND1 | c.1993G>T p.V665F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.033); catalogued as rs760241113; called by muse, varscan2
- IMPG1 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs370162508, COSV64055755; called by muse, mutect2, varscan2
- ITPRID1 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs142885665; called by muse, mutect2, varscan2
- HDAC5 | c.1147A>C p.T383P | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OLFML1 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- PPARA | c.509-1_509insAGG p.X170_splice | Splice Site (INS) | VAF 37/88 reads (42%) | called by mutect2, varscan2
- PPARA | c.509delinsAGGT p.A170delinsEV | Splice Region (INS) | VAF 48/104 reads (46%) | called by mutect2*, pindel, varscan2*
- SMC1A | c.3344G>A p.C1115Y | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC090517.4 | c.2151C>T p.A717= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- LRP8 | c.318C>T p.D106= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs757027968; called by muse, mutect2, varscan2
- C1orf105 | c.*49G>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as rs777381525; called by muse, mutect2, varscan2
- LY6E | c.-28T>C | 5'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SCNN1D | c.-349A>T | 5'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
